Somatic mutation profile of tumor specimen TCGA-77-8156-01A (aliquot TCGA-77-8156-01A-11D-2244-08) from TCGA case TCGA-77-8156, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.8 years (22,198 days).
Specimen TCGA-77-8156-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41e3ff93-7a6e-42c6-a776-36827eb4172c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8156-10A (Blood Derived Normal), aliquot TCGA-77-8156-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77a22f47-15f1-4829-9985-209d5e9d546e

The open-access MAF lists 218 somatic variants for this specimen: 155 protein-altering or splice-affecting, 61 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 61, Nonsense Mutation 7, Splice Region 4, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.1405C>G p.Q469E (on ENST00000404938 / NM_001163941.2; = p.Q24E on NM_178559.6) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99329286; called by muse, mutect2, varscan2
- ABCB8 | c.1618A>C p.T540P (on ENST00000297504 / NM_001282291.2; = p.T523P on NM_007188.5) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as COSV99874861; called by muse, mutect2, varscan2
- ABCC3 | c.2665C>A p.L889M | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV99559655; called by muse, mutect2, varscan2
- ABCG8 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs762440574, COSV99699404, COSV99700160; called by muse, mutect2
- AC005833.1 | c.1040A>T p.Y347F | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99363155; called by muse, mutect2
- AC008676.3 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.698); catalogued as COSV100400485; called by muse, mutect2
- ACSL1 | c.1833G>T p.W611C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99860870; called by mutect2, varscan2
- ACTL6B | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99355475, COSV99355708; called by muse, mutect2, varscan2
- ADGRB3 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs748456125, COSV101001623, COSV65401260, COSV65418191; called by muse, mutect2, varscan2
- ADGRB3 | c.822G>T p.R274S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV101001624; called by muse, mutect2, varscan2
- ADGRG4 | c.8629G>A p.G2877R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796387; called by muse, mutect2, varscan2
- ADGRG4 | c.8630G>T p.G2877V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796389; called by muse, mutect2, varscan2
- ARHGAP44 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV99311365; called by muse, mutect2
- ARRDC4 | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs760461342, COSV51419256; called by muse, mutect2, varscan2
- ASXL3 | c.3157A>G p.T1053A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52455797, COSV99326130; called by muse, mutect2
- ATN1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.12); catalogued as COSV100755931; called by muse, mutect2
- ATP13A2 | c.3374C>G p.T1125S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100454371; called by muse, mutect2, varscan2
- CACNA1A | c.5492C>G p.P1831R | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100803059; called by muse, mutect2
- CALCR | c.1120G>A p.V374I (on ENST00000649521 / NM_001164737.2; = p.V358I on NM_001742.4) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs375960623; called by muse, mutect2, varscan2
- CALN1 | c.547C>G p.Q183E (on ENST00000329008 / NM_001017440.3; = p.Q225E on NM_031468.4) | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100208729, COSV61128166; called by muse, mutect2, varscan2
- CD300E | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100151261; called by muse, mutect2
- CELSR2 | c.3916C>T p.R1306C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs766485813, COSV54772544; called by muse, mutect2
- CENPB | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.239); catalogued as COSV100713594; called by muse, mutect2
- COL5A3 | c.2406G>A p.K802= | Splice Region (SNP) | VAF 97/602 reads (16%) | catalogued as COSV99319566; called by muse, mutect2, varscan2
- CWF19L1 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV100821614; called by muse, mutect2, varscan2
- CXCR2 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV100579093, COSV59280337; called by muse, mutect2, varscan2
- DGKQ | c.2618A>C p.Q873P | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99298120; called by muse, mutect2
- DSG3 | c.314dup p.N105Kfs*6 | Frame Shift Ins (INS) | VAF 21/39 reads (54%) | catalogued as rs1568086848; called by mutect2, pindel, varscan2
- DST | c.7984C>G p.Q2662E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV99759065; called by muse, mutect2, varscan2
- DTD1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV101080017; called by muse, mutect2, varscan2
- DTD1 | c.617A>C p.E206A | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV101080019; called by muse, mutect2, varscan2
- DUOX1 | c.3871C>T p.R1291W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs369533234; called by mutect2, varscan2
- DZIP1L | c.1976A>T p.N659I | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV100551631; called by muse, mutect2
- DZIP3 | c.2675T>G p.V892G | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100847997; called by muse, mutect2, varscan2
- EGFR | c.3413A>G p.Y1138C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1562810543, COSV99294239; called by muse, mutect2, varscan2
- EGLN3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99164386; called by muse, mutect2, varscan2
- ELMO1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100165624; called by muse, mutect2
- ENTHD1 | c.203G>T p.W68L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289035; called by muse, mutect2, varscan2
- FAM120C | c.2489C>A p.T830K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100070400; called by muse, varscan2
- FAM155A | c.737G>C p.C246S | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101029795; called by muse, mutect2, varscan2
- FCGBP | c.267G>C p.M89I | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as rs746282192; called by muse, mutect2, varscan2
- FLT1 | c.2002A>T p.S668C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99165510; called by muse, mutect2, varscan2
- GAPDHS | c.493T>A p.Y165N | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99033235; called by muse, mutect2, varscan2
- GDF3 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325370; called by muse, mutect2
- GFPT2 | c.2023C>G p.L675V | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99517991; called by muse, mutect2, varscan2
- GNAL | c.618C>T p.F206= (on ENST00000269162 / NM_001142339.3; = p.F283= on NM_182978.4) | Splice Region (SNP) | VAF 9/118 reads (8%) | catalogued as COSV52326254, COSV99304042; called by muse, mutect2
- GPR63 | c.170G>C p.S57T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100013537; called by muse, mutect2, varscan2
- GREM2 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100547925; called by muse, mutect2, varscan2
- GTF3C1 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100649587, COSV100649642; called by muse, mutect2, varscan2
- HDHD5 | c.245G>T p.R82L (on ENST00000336737 / NM_033070.3; = p.R52L on NM_017829.5) | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.061); catalogued as COSV50086708; called by muse, mutect2, varscan2
- HRH2 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99199865; called by muse, mutect2, varscan2
- IGSF11 | c.100G>A p.V34M (on ENST00000393775 / NM_001015887.3; = p.V33M on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753373347, COSV100677746; called by muse, mutect2
- IGSF21 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV99245913; called by muse, mutect2, varscan2
- INSRR | c.638-1G>A p.X213_splice | Splice Site (SNP) | VAF 37/183 reads (20%) | catalogued as rs1236286108, COSV100947963; called by muse, mutect2, varscan2
- ISL1 | c.1012A>T p.T338S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as COSV57935563; called by muse, mutect2, varscan2
- ITIH3 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs781494651, COSV101407112; called by muse, mutect2, varscan2
- KCNK17 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs944848721, COSV100950287, COSV64684989; called by muse, mutect2
- KIF16B | c.573A>T p.L191F | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100734808; called by muse, mutect2
- KLHL25 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as COSV100563701, COSV100563763; called by muse, mutect2, varscan2
- KLHL3 | c.1181A>T p.D394V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100553490; called by muse, mutect2, varscan2
- KMT5C | c.522G>C p.W174C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99726300; called by muse, mutect2, varscan2
- KRTAP13-4 | c.330T>G p.S110R | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV100481812; called by muse, mutect2
- KSR2 | c.2230G>T p.G744* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100196387, COSV100196487; called by muse, mutect2, varscan2
- KSR2 | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100196390; called by muse, mutect2, varscan2
- LIMK1 | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 162/668 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100283403; called by muse, mutect2, varscan2
- LRP1 | c.11764G>A p.G3922S | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.411); catalogued as COSV99676880; called by muse, mutect2
- LRRTM4 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69141662; called by muse, mutect2, varscan2
- MAGI2 | c.1094A>G p.Y365C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100836061; called by muse, mutect2, varscan2
- MAML2 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV101594177; called by muse, mutect2, varscan2
- MAP3K13 | c.1133G>C p.C378S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99407750; called by muse, mutect2
- MCOLN1 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99900796; called by muse, mutect2, varscan2
- MECR | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99747329; called by muse, mutect2, varscan2
- METTL18 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99610086; called by muse, mutect2, varscan2
- MIEN1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.092); catalogued as COSV99508839; called by muse, mutect2
- MORC2 | c.2910C>A p.D970E (on ENST00000397641 / NM_001303256.3; = p.D908E on NM_014941.3) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99310298; called by muse, mutect2
- MUC16 | c.4241C>T p.P1414L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV101201058; called by muse, mutect2, varscan2
- MUC17 | c.9268G>T p.A3090S | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.935); catalogued as rs774669284, COSV100074711; called by muse, mutect2
- MUC5B | c.6187C>A p.P2063T | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1305613189, COSV101500655; called by muse, mutect2, varscan2
- MYOM1 | c.3058G>A p.G1020S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); catalogued as COSV99867979; called by muse, mutect2
- MYOZ3 | c.303C>A p.N101K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV99770849; called by muse, mutect2, varscan2
- N4BP2L1 | c.474-1G>C p.X158_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100583095; called by muse, mutect2, varscan2
- NAPEPLD | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV100439994; called by muse, varscan2
- NAV3 | c.4018A>G p.T1340A | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV99894439; called by muse, mutect2
- NEK7 | c.494C>G p.A165G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV100954748; called by muse, mutect2, varscan2
- NLRP13 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as rs769146950, COSV100738435, COSV61621464; called by muse, mutect2, varscan2
- NODAL | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.645); catalogued as COSV99755592; called by muse, mutect2, varscan2
- NOTCH4 | c.2575T>G p.C859G | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100900921; called by muse, mutect2
- NRXN3 | c.1761G>T p.E587D (on ENST00000335750 / NM_001330195.2; = p.E214D on NM_004796.6) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV100207679; called by muse, mutect2, varscan2
- OGDHL | c.2062G>A p.V688M | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.738); catalogued as COSV100934477; called by muse, mutect2
- OR10H2 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as rs368469319, COSV99045397; called by muse, mutect2, varscan2
- OR2G2 | c.643T>A p.S215T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.842); catalogued as COSV100189926; called by muse, mutect2, varscan2
- OR2T1 | c.879C>A p.N293K | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV100822347; called by muse, mutect2, varscan2
- OR4D11 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.273); catalogued as COSV100506621; called by muse, mutect2
- OR4D6 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV100271516, COSV100271805; called by muse, mutect2, varscan2
- OR4K1 | c.509del p.G170Vfs*15 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | catalogued as COSV53461071; called by mutect2, pindel, varscan2
- OR8D2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100659079, COSV62488199; called by muse, mutect2, varscan2
- OR9G4 | c.289T>G p.C97G | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100265233; called by muse, mutect2
- OSTN | c.301C>G p.H101D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.569); catalogued as COSV100174315; called by muse, mutect2, varscan2
- PCDHA8 | c.2042G>T p.R681M | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); catalogued as COSV100969984; called by muse, mutect2, varscan2
- PCLO | c.15367G>T p.D5123Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427722; called by muse, mutect2, varscan2
- PCLO | c.3748C>G p.P1250A | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100436521, COSV100438612; called by muse, mutect2, varscan2
- PDE1C | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); catalogued as COSV100373532; called by muse, mutect2, varscan2
- PIK3C2G | c.3347C>A p.T1116N (on ENST00000676171; = p.T1075N on NM_004570.5) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99853504; called by muse, mutect2, varscan2
- PLIN4 | c.1414G>T p.G472C (on ENST00000301286; = p.G487C on NM_001367868.2) | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV100013926; called by muse, mutect2
- PLXNA4 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs190791576, COSV58103413; called by muse, mutect2
- PTPRH | c.536A>T p.E179V | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as COSV99671372; called by muse, mutect2, varscan2
- RADX | c.2227A>C p.K743Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV100998903; called by muse, mutect2, varscan2
- RBFA | c.892G>C p.G298R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100080291; called by muse, mutect2, varscan2
- RBM26 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as COSV99936502; called by muse, mutect2, varscan2
- REM1 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99147660; called by muse, mutect2, varscan2
- REV3L | c.4401C>G p.I1467M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100725587; called by muse, mutect2, varscan2
- RIN2 | c.946G>C p.G316R (on ENST00000255006 / NM_001242581.1; = p.G267R on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs766561913, COSV54785184, COSV99657698; called by muse, mutect2, varscan2
- RUNX1T1 | c.1357G>T p.V453F (on ENST00000265814 / NM_001198628.1; = p.V426F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99749787, COSV99754196; called by muse, mutect2, varscan2
- RUNX2 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.98); PolyPhen probably damaging (0.982); catalogued as COSV100177939; called by muse, mutect2, varscan2
- SCARA3 | c.225G>C p.L75= | Splice Region (SNP) | VAF 52/227 reads (23%) | catalogued as COSV100107007; called by muse, mutect2, varscan2
- SEC31B | c.1148G>T p.W383L | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100944908; called by muse, mutect2, varscan2
- SLC4A1AP | c.1856T>G p.L619* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100389582; called by muse, mutect2
- SLC6A19 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 20/301 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100443701; called by muse, mutect2
- SMS | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs746297985, COSV65113563; called by mutect2, varscan2
- ST6GALNAC5 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | PolyPhen benign (0.401); catalogued as COSV100602991; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100562161, COSV59135095; called by muse, mutect2
- STYXL2 | c.2137G>T p.G713W | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99608438; called by muse, mutect2
- TAFA4 | c.368C>A p.S123* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99807820; called by muse, mutect2, varscan2
- TAGAP | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100487606; called by muse, mutect2, varscan2
- TMEM86A | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99773844; called by muse, mutect2, varscan2
- TP53 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52689817, COSV52759537, COSV52925149; called by muse, mutect2, varscan2
- TRAM2 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.438); catalogued as COSV99480368; called by muse, mutect2, varscan2
- TRIM3 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100624263, COSV100624518; called by muse, mutect2, varscan2
- TSHZ3 | c.1676T>A p.M559K | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV53664363, COSV99552452; called by muse, mutect2, varscan2
- TTI2 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.148); catalogued as COSV100659791; called by muse, mutect2, varscan2
- TTLL9 | c.1018G>T p.V340F | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1309053602, COSV100207159; called by muse, mutect2
- TTN | c.78020C>A p.A26007D (on ENST00000591111; = p.A18583D on NM_003319.4) | Missense Mutation (SNP) | VAF 50/168 reads (30%) | PolyPhen probably damaging (0.999); catalogued as COSV100625771, COSV60014613; called by muse, mutect2, varscan2
- TTN | c.72395C>T p.A24132V (on ENST00000591111; = p.A16708V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | PolyPhen probably damaging (0.995); catalogued as COSV60067260; called by muse, mutect2, varscan2
- TUBG1 | c.611T>G p.V204G | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99258875; called by muse, mutect2, varscan2
- TUBG2 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99257939; called by muse, mutect2
- TXNIP | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.276); catalogued as COSV100997323; called by muse, mutect2
- UBASH3B | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 61/391 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.058); catalogued as COSV99418607; called by muse, mutect2, varscan2
- UMPS | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1480571861, COSV99229249; called by muse, mutect2
- VNN1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 14/147 reads (10%) | catalogued as COSV100907816, COSV63389205; called by muse, mutect2
- VNN1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as COSV100907817; called by muse, mutect2
- VSIG8 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200899435, COSV63652845; called by muse, mutect2, varscan2
- ZNF180 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV99660042; called by muse, mutect2, varscan2
- ZNF208 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as COSV68101588, COSV68107479; called by muse, mutect2
- ZNF614 | c.18A>G p.E6= | Splice Region (SNP) | VAF 7/91 reads (8%) | catalogued as COSV99571934; called by muse, mutect2
- ZNF791 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100589153; called by muse, mutect2, varscan2
- ZSWIM4 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54326584; called by muse, mutect2, varscan2
- CCDC60 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.087); called by muse, mutect2
- CPSF1 | c.22del p.A8Rfs*24 | Frame Shift Del (DEL) | VAF 24/216 reads (11%) | called by mutect2, varscan2
- ERICH3 | c.2845dup p.A949Gfs*23 | Frame Shift Ins (INS) | VAF 37/156 reads (24%) | called by mutect2, pindel, varscan2
- FCGBP | c.268G>T p.V90F | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC17 | c.7318A>T p.T2440S | Missense Mutation (SNP) | VAF 81/913 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.636); called by muse, mutect2
- PCGF1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2
- SRPK2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- TRAM1L1 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.31); called by muse, mutect2
- TRGV5 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ABCB1 | c.3654G>A p.L1218= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs957128606, COSV99714028; called by muse, mutect2, varscan2
- ABCC5 | c.3711G>A p.G1237= | Silent (SNP) | VAF 14/264 reads (5%) | catalogued as rs1468867616, COSV99657404; called by muse, mutect2
- ABCG8 | c.522G>T p.R174= | Silent (SNP) | VAF 29/419 reads (7%) | catalogued as COSV99700161; called by muse, mutect2
- ACHE | c.486C>T p.D162= | Silent (SNP) | VAF 15/189 reads (8%) | catalogued as rs775092798, COSV53823159; called by muse, mutect2
- ARHGAP19 | c.1068A>G p.V356= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs764066857, COSV100363297; called by muse, mutect2, varscan2
- ATP10A | c.2055G>A p.Q685= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100791453; called by muse, mutect2, varscan2
- ATP6V1G2 | c.300T>C p.L100= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs569374123, COSV100385467; called by muse, mutect2, varscan2
- ATXN2L | c.528G>A p.R176= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as rs770856056, COSV100294971; called by muse, mutect2, varscan2
- CACNA1A | c.3282G>T p.L1094= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100803060; called by muse, mutect2, varscan2
- CACNA2D1 | c.246A>T p.A82= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as COSV100667073; called by muse, mutect2, varscan2
- CD22 | c.1494C>A p.A498= | Silent (SNP) | VAF 43/163 reads (26%) | catalogued as COSV99323665; called by muse, mutect2, varscan2
- CD2AP | c.96A>G p.L32= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs758262794, COSV100830605; called by muse, mutect2, varscan2
- CD84 | c.660T>A p.R220= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV100246232; called by muse, mutect2, varscan2
- CNTN4 | c.1962G>T p.G654= | Silent (SNP) | VAF 20/218 reads (9%) | catalogued as rs1246734030, COSV100639581; called by muse, mutect2
- DAB2 | c.792T>C p.S264= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV100298248; called by muse, mutect2, varscan2
- DEFA5 | c.225T>G p.R75= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100400482; called by muse, mutect2, varscan2
- DIPK2B | c.667C>T p.L223= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100933468; called by muse, mutect2, varscan2
- EHMT2 | c.1131C>T p.G377= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs778234280, COSV100977235; called by muse, mutect2
- EN1 | c.1152G>T p.T384= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV99727374; called by muse, mutect2, varscan2
- FANCI | c.312A>G p.L104= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs914343886, COSV100168437; called by muse, mutect2, varscan2
- FCGBP | c.660G>T p.V220= | Silent (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- GABBR1 | c.2367T>C p.Y789= | Silent (SNP) | VAF 44/168 reads (26%) | catalogued as COSV100589964; called by muse, mutect2, varscan2
- GRID2 | c.2499G>T p.G833= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99945226; called by muse, mutect2, varscan2
- HERC1 | c.669G>A p.S223= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs1237843217, COSV71247536; called by muse, mutect2, varscan2
- HERPUD2 | c.33C>T p.T11= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV60945601; called by muse, mutect2, varscan2
- ITGAM | c.2535C>T p.R845= (on ENST00000648685 / NM_001145808.2; = p.R844= on NM_000632.4) | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV99792976; called by muse, mutect2, varscan2
- KCNK16 | c.588C>T p.G196= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as COSV100949288; called by muse, mutect2
- LAMB4 | c.4359C>T p.S1453= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99225269; called by muse, mutect2, varscan2
- MARCHF7 | c.1950C>T p.C650= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs374695356; called by mutect2, varscan2
- MAST4 | c.6849C>T p.D2283= (on ENST00000403625 / NM_001164664.2; = p.D2094= on NM_015183.3) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs762560806, COSV99845422; called by muse, mutect2, varscan2
- MDGA2 | c.1407A>G p.T469= (on ENST00000399232 / NM_001113498.2; = p.T171= on NM_182830.4) | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100637274; called by muse, mutect2, varscan2
- MTNR1A | c.960T>C p.F320= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV100208297; called by muse, mutect2, varscan2
- MYBPH | c.414A>G p.G138= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99704120; called by muse, mutect2, varscan2
- NXPH1 | c.582T>C p.C194= | Silent (SNP) | VAF 2/10 reads (20%) | catalogued as COSV101339773; called by muse, mutect2
- OGDHL | c.1344G>T p.P448= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as rs770910107, COSV100934478, COSV65103977; called by muse, mutect2
- OLIG3 | c.90C>T p.H30= | Silent (SNP) | VAF 19/154 reads (12%) | catalogued as COSV100880319; called by muse, mutect2, varscan2
- OR10G8 | c.546C>A p.P182= | Silent (SNP) | VAF 20/338 reads (6%) | catalogued as COSV101461864; called by muse, mutect2
- OR2T12 | c.597C>A p.I199= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as COSV100527940; called by muse, mutect2, varscan2
- OR4D6 | c.138G>T p.V46= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100271803; called by muse, mutect2, varscan2
- OR56A1 | c.156C>T p.I52= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100360528; called by muse, mutect2, varscan2
- OR5D18 | c.528T>C p.N176= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV100450837; called by muse, mutect2, varscan2
- OR9A2 | c.555C>T p.C185= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs372529476; called by mutect2, varscan2
- P2RY13 | c.279A>T p.T93= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99854320; called by muse, mutect2, varscan2
- PCDHGA4 | c.1569C>T p.A523= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs773817412, COSV54016585, COSV99544742; called by muse, mutect2, varscan2
- PCDHGA5 | c.1659G>C p.L553= | Silent (SNP) | VAF 93/376 reads (25%) | catalogued as COSV99544747; called by muse, mutect2, varscan2
- PNLDC1 | c.130C>T p.L44= | Silent (SNP) | VAF 19/210 reads (9%) | catalogued as rs1018973227, COSV99277768; called by muse, mutect2, varscan2
- PNLIPRP1 | c.516G>T p.L172= | Silent (SNP) | VAF 44/480 reads (9%) | catalogued as COSV100724185, COSV100724502; called by muse, mutect2
- SEZ6L | c.1908T>A p.A636= | Silent (SNP) | VAF 33/198 reads (17%) | catalogued as COSV99962696; called by muse, mutect2, varscan2
- SORBS2 | c.2415C>T p.C805= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs572897258, COSV99512325; called by muse, mutect2, varscan2
- SPTBN5 | c.9063C>T p.V3021= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100312052; called by muse, mutect2
- STYXL2 | c.2136G>T p.V712= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV99609736; called by muse, mutect2
- TET1 | c.5646G>T p.T1882= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as COSV101018765, COSV65382167; called by muse, mutect2
- TP53 | c.1002G>T p.G334= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99439495; called by muse, mutect2, varscan2
- TRPM3 | c.4059T>C p.G1353= (on ENST00000357533 / NM_001366142.2; = p.G1208= on NM_020952.6) | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100678386; called by muse, mutect2, varscan2
- TRUB2 | c.924C>T p.P308= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs981840495, COSV100867914, COSV65760177; called by muse, mutect2, varscan2
- TTN | c.78021C>T p.A26007= (on ENST00000591111; = p.A18583= on NM_003319.4) | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as COSV60268214; called by muse, mutect2, varscan2
- USF3 | c.6366C>T p.S2122= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV100325675; called by muse, mutect2, varscan2
- USH2A | c.14553C>A p.P4851= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as rs1346992183, COSV100240605, COSV56397671; called by muse, mutect2, varscan2
- UTP18 | c.1638G>T p.L546= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99834913; called by muse, mutect2, varscan2
- WSCD1 | c.114C>T p.V38= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100496759; called by muse, mutect2
- YY1AP1 | c.129C>G p.T43= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV99804535; called by muse, mutect2, varscan2
- DPP6 | c.*485G>T | 3'UTR (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100127523; called by muse, mutect2, varscan2
- NDUFA5 | c.66+650G>T | Intron (SNP) | VAF 7/31 reads (23%) | catalogued as rs554320195; called by muse, mutect2, varscan2
